Somatic mutation profile of tumor specimen TCGA-AJ-A3BF-01A (aliquot TCGA-AJ-A3BF-01A-11D-A20S-09) from TCGA case TCGA-AJ-A3BF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 65.5 years (23,906 days).
Specimen TCGA-AJ-A3BF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 504f2f05-2893-49aa-a7ff-ab49e1659637.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3BF-10A (Blood Derived Normal), aliquot TCGA-AJ-A3BF-10A-01D-A20S-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6921a15-18cf-449f-95e4-b8081e58ed78

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 19/27 reads (70%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP35 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 63/71 reads (89%) | catalogued as COSV68334058; called by muse, mutect2, varscan2
- CDK18 | c.1199C>G p.A400G (on ENST00000506784 / NM_212503.3; = p.A370G on NM_002596.4) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100774092; called by muse, mutect2, varscan2
- CHD5 | c.4685C>T p.P1562L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs781286534, COSV99314701; called by muse, mutect2, varscan2
- CLUH | c.1276_1278del p.F426del (on ENST00000435359; = p.F464del on NM_015229.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 24/37 reads (65%) | catalogued as rs1373538192; called by pindel, varscan2
- COL6A6 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as rs770189741, COSV62016903, COSV62034742; called by muse, mutect2, varscan2
- COL7A1 | c.7037G>A p.R2346H | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs201432371, COSV60392298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FTSJ1 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99191444; called by muse, mutect2
- GLP1R | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 20/111 reads (18%) | catalogued as COSV100952712; called by muse, mutect2, varscan2
- GYS1 | c.1549G>T p.A517S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs1233369798, COSV99621114; called by muse, mutect2, varscan2
- H2AC21 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.065); catalogued as rs373049405, COSV100480129; called by muse, mutect2, varscan2
- KEAP1 | c.1475C>G p.P492R | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99408188; called by muse, mutect2, varscan2
- MIA3 | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs761603506, COSV100719525; called by muse, mutect2
- MYO16 | c.3479G>T p.G1160V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100697116; called by muse, mutect2, varscan2
- SH3KBP1 | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV101115097; called by muse, mutect2, varscan2
- SLC6A3 | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780134296, COSV99548378; called by muse, mutect2, varscan2
- SRRM2 | c.7868C>T p.S2623F | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs763045577, COSV99241678; called by muse, mutect2, varscan2
- TEX10 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs750647749, COSV100887946; called by muse, mutect2, varscan2
- WWC3 | c.2806T>C p.S936P | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.413); catalogued as COSV101081706; called by muse, mutect2
- ZNF697 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV70284001; called by muse, mutect2, varscan2
- BCL2L11 | c.395-1del p.X132_splice (on ENST00000393256 / NM_138621.5; = p.X72_splice on NM_006538.5) | Splice Site (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- IGKV1-6 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KCNAB1 | c.768del p.Q256Hfs*4 (on ENST00000490337 / NM_172160.3; = p.Q245Hfs*4 on NM_003471.3) | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- NNT | c.2642del p.N881Ifs*7 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- RIMS2 | c.170del p.V57Gfs*16 | Frame Shift Del (DEL) | VAF 9/15 reads (60%) | called by mutect2, varscan2
- CHAT | c.1221C>T p.L407= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100340537, COSV60333427; called by muse, mutect2, varscan2
- COBLL1 | c.3255C>T p.A1085= (on ENST00000392717; = p.A1047= on NM_014900.5) | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs775713851, COSV99528578; called by muse, mutect2, varscan2
- LMO3 | c.231C>T p.C77= | Silent (SNP) | VAF 16/19 reads (84%) | catalogued as rs149014326; called by muse, mutect2, varscan2
- MAP3K15 | c.3807G>A p.S1269= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs140779387, COSV100135472; called by muse, mutect2, varscan2
- OPN1MW | c.822C>A p.V274= | Silent (SNP) | VAF 116/368 reads (32%) | called by muse, mutect2, varscan2
- OR56B1 | c.118C>T p.L40= | Silent (SNP) | VAF 44/67 reads (66%) | catalogued as COSV100402709, COSV99061119; called by muse, mutect2, varscan2
- ZNF253 | c.354C>T p.S118= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs1044280022, COSV100849459; called by muse, mutect2
